Gene-level copy-number profile of tumor specimen TCGA-13-0901-01B from TCGA case TCGA-13-0901, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.0 years (15,333 days).
Specimen TCGA-13-0901-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.98468e98-0f7c-42ab-8271-97b2fb98d206.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0901-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7aac4bd6-fcc0-4402-8c64-3a416f00f38a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,335; copy number 2: 10,443; copy number 3: 23,516; copy number 4: 17,919; copy number 5: 3,076; copy number 6: 1,254; copy number 7: 298; copy number 8: 47; copy number 9: 414; copy number 10: 42; copy number 11: 34; copy number 13: 16; copy number 14: 195; copy number 16: 1; copy number 17: 16; copy number 18: 17; copy number 19: 30; copy number 21: 11; copy number 22: 58; copy number 29: 34; copy number 30: 17; copy number 34: 21; copy number 37: 19; copy number 43: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0901-01): tumor purity 0.78, ploidy 3.32, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,097 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:156,011,530–164,352,223, 107 genes, copy number 7–14 (within-gene range 5–14) (broad region; genes not listed).
- chr2:178,194,481–179,264,832, 22 genes, copy number 11 (within-gene range 3–11): OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2, FKBP7, PLEKHA3, TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1, AC092640.1, CCDC141, RNU7-104P, RPS6P2, SESTD1.
- chr3:88,338,416–89,590,097, 9 genes, copy number 19–43 (within-gene range 3–43): CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6.
- chr4:499,210–1,808,872, 48 genes, copy number 22–34: PIGG, TMEM271, AC116565.1, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3, PCGF3, AC107464.1, AC139887.4, AC139887.2, AC139887.1, CPLX1, AC139887.3, AC139887.5, GAK, TMEM175, DGKQ, SLC26A1, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3.
- chr4:22,345,071–22,611,063, 3 genes, copy number 11: ADGRA3, AC098583.1, AC098583.2.
- chr4:56,907,876–58,118,070, 19 genes, copy number 7 (within-gene range 6–7): REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1.
- chr6:61,679,961–62,611,327, 5 genes, copy number 8 (within-gene range 5–8): KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr6:71,075,564–72,403,143, 20 genes, copy number 8–14 (within-gene range 2–14): BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1.
- chr6:89,876,544–94,447,179, 41 genes, copy number 7: RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7, AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr7:48,171,458–49,921,950, 12 genes, copy number 8 (within-gene range 3–8): ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C, AC091730.1, DDX43P2, AC092448.1, AC093775.1, VWC2.
- chr7:49,942,251–49,944,440, 1 gene, copy number 8: GNL2P1.
- chr8:126,556,323–127,419,050, 1 gene, copy number 9 (within-gene range 2–9): PCAT1.
- chr8:126,766,196–130,443,674, 51 genes, copy number 9 (within-gene range 2–9): AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1.
- chr8:131,904,093–138,083,657, 69 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr12:5,032,388–8,216,151, 144 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:17,383,352–18,320,107, 7 genes, copy number 9: PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL.
- chr12:18,358,443–18,358,967, 1 gene, copy number 9: NDFIP1P1.
- chr12:42,929,848–43,054,386, 4 genes, copy number 9: AC068802.1, AC012038.2, AC012038.1, MRPS36P5.
- chr12:43,560,784–43,661,101, 4 genes, copy number 8: AC090525.1, AC090525.2, AC090525.3, EEF1A1P17.
- chr12:44,508,275–46,876,784, 34 genes, copy number 29 (within-gene range 2–29): NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:47,205,898–47,485,722, 11 genes, copy number 18: PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1.
- chr12:56,822,985–60,341,941, 101 genes, copy number 7–9 (broad region; genes not listed).
- chr12:69,326,574–71,118,247, 35 genes, copy number 19–37: AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr12:125,983,702–126,511,711, 11 genes, copy number 21: LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1.
- chr12:126,610,034–126,772,519, 8 genes, copy number 19 (within-gene range 4–19): AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944.
- chr12:126,912,034–127,207,706, 7 genes, copy number 11: HSPE1P20, LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6.
- chr14:18,333,726–22,190,713, 250 genes, copy number 9 (broad region; genes not listed).
- chr14:22,202,583–22,227,254, 4 genes, copy number 9: TRAV26-2, TRAV34, TRAV35, TRAV36DV7.
- chr14:28,264,390–29,500,460, 22 genes, copy number 8–17: BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P.
- chr14:29,652,809–29,812,018, 2 genes, copy number 11: AL356756.1, RNU6-1234P.
- chr20:87,250–348,490, 12 genes, copy number 7: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12.
- chr22:29,554,808–30,378,658, 31 genes, copy number 22 (within-gene range 4–22): NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157.
- chr22:34,191,194–34,210,564, 1 gene, copy number 16: Z68323.1.

Autosomal genes at a single copy (total copy number 1): 2,335. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
